Somatic mutation profile of tumor specimen TCGA-49-6743-01A (aliquot TCGA-49-6743-01A-11D-1855-08) from TCGA case TCGA-49-6743, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 81.6 years (29,807 days).
Specimen TCGA-49-6743-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79ca68ff-75d8-4ccd-908a-15fe74d2d217.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-6743-11A (Solid Tissue Normal), aliquot TCGA-49-6743-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2261346f-f46d-4137-8739-a2b97855b1b3

The open-access MAF lists 801 somatic variants for this specimen: 592 protein-altering or splice-affecting, 194 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 509, Silent 194, Nonsense Mutation 42, Frame Shift Del 21, Splice Site 15, Intron 8, RNA 4, Frame Shift Ins 3, Splice Region 2, 5'Flank 2, 3'UTR 1.

Variants (750 of 801; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYA4 | c.455T>A p.L152H | Missense Mutation (SNP) | VAF 16/176 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62044745, COSV62052190, COSV62055739; called by muse, mutect2
- PDHA1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs863224147, CM961098, COSV58825380, COSV58827746; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.912T>A p.H304Q | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs776578060, COSV60197910; called by muse, mutect2, varscan2
- ABCA10 | c.1018C>A p.H340N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV52217474; called by muse, mutect2, varscan2
- ABCA12 | c.6152G>T p.G2051V (on ENST00000272895 / NM_173076.3; = p.G1733V on NM_015657.3) | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV55947619; called by muse, mutect2, varscan2
- ABCA2 | c.3862A>G p.I1288V (on ENST00000614293; = p.I1258V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.159); catalogued as COSV55796747; called by muse, mutect2
- ABCA5 | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1438450341, COSV67015505; called by muse, mutect2, varscan2
- ABCB4 | c.2515A>T p.I839L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as COSV55931490; called by muse, mutect2, varscan2
- ABCC3 | c.1337A>T p.Q446L | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); catalogued as COSV99558941; called by muse, mutect2, varscan2
- ABCC9 | c.1195T>C p.S399P | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53961429; called by muse, mutect2, varscan2
- ABCD4 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV53990581; called by muse, mutect2, varscan2
- ABL2 | c.2488A>T p.N830Y (on ENST00000502732 / NM_007314.4; = p.N815Y on NM_005158.5) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV61010698; called by muse, mutect2, varscan2
- AC005324.2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.234); catalogued as COSV100371809; called by muse, mutect2, varscan2
- ACAN | c.668A>G p.D223G | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61354964; called by muse, mutect2
- ACAP3 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1460433500, COSV100329708; called by muse, mutect2, varscan2
- ACKR1 | c.699G>C p.K233N | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV63671560; called by muse, mutect2
- ACTG2 | c.998C>A p.P333H | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61827316; called by muse, mutect2, varscan2
- ACTN1 | c.2244G>A p.M748I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99517565; called by muse, mutect2, varscan2
- ACTR3B | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55445946; called by muse, mutect2, varscan2
- ADAM23 | c.658G>C p.G220R | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52206551; called by muse, mutect2, varscan2
- ADAMTS12 | c.4090C>T p.P1364S | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61254386; called by muse, mutect2, varscan2
- ADCY1 | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.312); catalogued as COSV52029365; called by muse, mutect2, varscan2
- ADCY8 | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as COSV99651516; called by muse, mutect2, varscan2
- ADCY8 | c.2395G>T p.G799C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.626); catalogued as COSV99651521; called by muse, mutect2, varscan2
- ADCYAP1 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99327485; called by muse, mutect2, varscan2
- ADD3 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV53319828; called by muse, mutect2, varscan2
- ADGRB3 | c.3476G>C p.R1159T | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV53232897; called by muse, mutect2
- ADGRL4 | c.877+1G>T p.X293_splice | Splice Site (SNP) | VAF 26/226 reads (12%) | catalogued as rs1236522482, COSV66058626; called by muse, mutect2, varscan2
- AGTR1 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs1400159105, COSV62557114; called by muse, mutect2, varscan2
- AL592490.1 | c.1552A>C p.K518Q | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV69424295; called by muse, mutect2
- AL592490.1 | c.1550T>G p.V517G | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV69424305; called by muse, mutect2
- ALPG | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104402087, COSV54964645; called by muse, mutect2, varscan2
- ANKRD33 | c.76C>A p.Q26K (on ENST00000340970 / NM_001304459.2; = p.Q161K on NM_182608.4) | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56604798; called by muse, mutect2, varscan2
- ANOS1 | c.1790G>A p.R597K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as COSV99390689; called by muse, mutect2, varscan2
- AOX1 | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65979734; called by muse, mutect2
- APOB | c.2015T>A p.M672K | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV51921301; called by muse, mutect2, varscan2
- ARAP1 | c.4228C>T p.R1410W (on ENST00000393609 / NM_001040118.2; = p.R1165W on NM_015242.4) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs778819957, COSV61989122; called by muse, mutect2, varscan2
- ARFGAP2 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53562488; called by muse, mutect2, varscan2
- ARHGAP1 | c.318G>A p.G106= | Splice Region (SNP) | VAF 8/98 reads (8%) | catalogued as rs1460158986, COSV61734169; called by muse, mutect2
- ARHGAP29 | c.1196G>C p.R399T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV53107556; called by mutect2, varscan2
- ARHGEF6 | c.1204C>A p.Q402K | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.009); catalogued as COSV51687097, COSV99166468; called by muse, mutect2, varscan2
- ARID1B | c.6696G>C p.Q2232H | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV51646944; called by muse, mutect2, varscan2
- ARID3C | c.1159C>A p.Q387K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as COSV99426821; called by muse, mutect2, varscan2
- ATG3 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51925672, COSV51926607; called by muse, mutect2
- ATP13A4 | c.2581G>A p.V861M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs143538005; called by muse, mutect2, varscan2
- ATRNL1 | c.1830C>A p.Y610* | Nonsense Mutation (SNP) | VAF 32/131 reads (24%) | catalogued as COSV61796032; called by muse, mutect2, varscan2
- AVPR1B | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100899348; called by muse, mutect2, varscan2
- BACE2 | c.393C>A p.D131E | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.471); catalogued as COSV57736976; called by muse, mutect2, varscan2
- BAZ2B | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV58595035; called by muse, mutect2, varscan2
- BCAS1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV65083388; called by muse, mutect2, varscan2
- BCORL1 | c.3286G>T p.V1096L | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.031); catalogued as COSV54388855, COSV54409042; called by muse, varscan2
- BICC1 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54061624, COSV54064111; called by muse, mutect2, varscan2
- BLVRA | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV99645948; called by muse, mutect2, varscan2
- BMS1 | c.2260A>G p.I754V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV65732744; called by muse, mutect2
- BPIFA2 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV53610100; called by muse, mutect2, varscan2
- BTBD3 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54777556, COSV54780413; called by muse, mutect2, varscan2
- BUD13 | c.344C>G p.S115* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV52766735; called by muse, mutect2, varscan2
- C5orf22 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.089); catalogued as COSV57597323; called by muse, mutect2, varscan2
- CACNA1E | c.2705G>A p.G902E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1291056979, COSV62380948; called by muse, mutect2, varscan2
- CACNA1F | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV100544537, COSV59902763; called by muse, mutect2, varscan2
- CACNA2D1 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV62371388; called by muse, mutect2, varscan2
- CACNB2 | c.1648T>C p.S550P (on ENST00000324631 / NM_201596.3; = p.S495P on NM_000724.4) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56610514; called by muse, mutect2
- CALD1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as rs1426278025, COSV62644688; called by muse, mutect2
- CALN1 | c.145G>T p.D49Y (on ENST00000329008 / NM_001017440.3; = p.D91Y on NM_031468.4) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61117376, COSV61152282; called by muse, mutect2
- CASS4 | c.479G>T p.R160I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV64385276; called by muse, mutect2, varscan2
- CASZ1 | c.4138G>T p.V1380L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.993); catalogued as rs375809156, COSV100680870; called by muse, varscan2
- CATSPERE | c.2378A>G p.Y793C | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759785816, COSV63675519; called by muse, mutect2, varscan2
- CBX6 | c.595C>A p.R199S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53321440, COSV99328053; called by muse, mutect2, varscan2
- CCAR1 | c.1751C>G p.S584* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as rs974239648, COSV56266753, COSV99771055; called by muse, mutect2
- CCDC136 | c.2827C>G p.Q943E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52795911; called by muse, mutect2, varscan2
- CCDC39 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56477668, COSV99867362; called by muse, mutect2, varscan2
- CCHCR1 | c.574A>T p.S192C | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66182498; called by muse, mutect2, varscan2
- CCNB3 | c.1827G>C p.K609N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.213); catalogued as COSV52069369; called by muse, varscan2
- CCPG1 | c.440G>A p.C147Y | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV60523848; called by muse, mutect2
- CCZ1 | c.1288A>C p.I430L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV100382767; called by mutect2, varscan2
- CD1E | c.393G>C p.M131I | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV63769814; called by muse, mutect2, varscan2
- CD226 | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.686); catalogued as COSV54609775; called by muse, mutect2, varscan2
- CD33 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV51799661; called by muse, mutect2, varscan2
- CDCA2 | c.919G>T p.V307F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.41); catalogued as COSV57943993; called by muse, mutect2
- CDH11 | c.2244G>T p.R748S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.968); catalogued as COSV51750145; called by muse, mutect2
- CDH18 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.107); catalogued as COSV56897805; called by muse, varscan2
- CDH4 | c.1648C>A p.P550T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.967); catalogued as COSV64640657, COSV64644245; called by muse, mutect2, varscan2
- CDH9 | c.789C>A p.N263K | Missense Mutation (SNP) | VAF 79/323 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV50250741; called by muse, mutect2, varscan2
- CDHR1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs201731584, COSV60559174; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDR1 | c.608G>A p.W203* | Nonsense Mutation (SNP) | VAF 55/210 reads (26%) | catalogued as rs1232021306, COSV65163785; called by muse, mutect2, varscan2
- CENPE | c.2163G>C p.K721N | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as COSV54375385, COSV54378376; called by muse, mutect2, varscan2
- CEP152 | c.4301T>C p.V1434A (on ENST00000380950 / NM_001194998.2; = p.V1378A on NM_014985.4) | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV57856208; called by muse, mutect2, varscan2
- CEP164 | c.976A>T p.N326Y | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV54037704; called by muse, mutect2, varscan2
- CEP85L | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63820482, COSV63820833; called by muse, mutect2, varscan2
- CFAP58 | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV57211158; called by muse, mutect2, varscan2
- CHN1 | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55031873; called by muse, mutect2, varscan2
- CLEC9A | c.519C>A p.Y173* | Nonsense Mutation (SNP) | VAF 33/127 reads (26%) | catalogued as COSV100191291; called by muse, mutect2, varscan2
- CLN8 | c.801G>T p.Q267H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs374652311, COSV100486019; called by muse, mutect2, varscan2
- CLSTN2 | c.362C>A p.T121K | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.895); catalogued as COSV71717570; called by muse, mutect2, varscan2
- CLSTN2 | c.1362G>T p.W454C | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71717573; called by muse, mutect2, varscan2
- CLUL1 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV58111060; called by muse, mutect2, varscan2
- CNIH3 | c.400del p.E134Rfs*20 | Frame Shift Del (DEL) | VAF 28/140 reads (20%) | catalogued as COSV55280166; called by mutect2, varscan2
- CNKSR2 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV54248616; called by muse, mutect2
- CNOT7 | c.56A>T p.N19I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61352454; called by muse, mutect2, varscan2
- COL11A1 | c.4609-1G>T p.X1537_splice | Splice Site (SNP) | VAF 14/101 reads (14%) | catalogued as COSV62179245, COSV62185011; called by muse, mutect2, varscan2
- COL19A1 | c.1910C>A p.A637D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.417); catalogued as COSV59564152; called by muse, mutect2, varscan2
- COL21A1 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1040526013, COSV55152168; called by muse, mutect2
- COL4A1 | c.3581C>T p.P1194L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372606485; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.845C>G p.S282* | Nonsense Mutation (SNP) | VAF 38/163 reads (23%) | catalogued as COSV62016595, COSV62020386; called by muse, mutect2, varscan2
- COP1 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.968); catalogued as COSV58162330, COSV58169630; called by muse, mutect2, varscan2
- CPED1 | c.2552C>T p.T851I | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV59996307; called by muse, mutect2
- CPXM1 | c.1492C>A p.H498N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV66044491; called by muse, mutect2, varscan2
- CPXM1 | c.1038T>G p.H346Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66044497; called by muse, mutect2, varscan2
- CRELD2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs756156702, COSV60302801; called by muse, mutect2
- CREM | c.870G>T p.E290D (on ENST00000429130; = p.E245D on NM_181571.3) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59764616; called by muse, mutect2, varscan2
- CSNK1E | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs868029992, COSV63290315; called by muse, mutect2, varscan2
- CST4 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 16/162 reads (10%) | catalogued as rs767756120; called by mutect2, pindel, varscan2
- CTSB | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV100565834; called by muse, mutect2
- CUL9 | c.3201G>A p.M1067I | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV52724409; called by muse, mutect2
- CUL9 | c.3319G>C p.E1107Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV52724420; called by muse, mutect2, varscan2
- CWF19L2 | c.1202T>C p.L401S | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV56507844; called by muse, mutect2, varscan2
- CWH43 | c.1054C>T p.L352F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1215456344, COSV56935434; called by muse, mutect2, varscan2
- CYP2C19 | c.1238T>C p.L413P | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64906613; called by muse, mutect2, varscan2
- CYSLTR1 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100964713; called by muse, mutect2, varscan2
- DAB1 | c.804G>C p.E268D | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100976238; called by muse, mutect2, varscan2
- DACH1 | c.1375C>A p.H459N (on ENST00000619232 / NM_001366712.1; = p.H407N on NM_080759.6) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.519); catalogued as rs1193165198, COSV57487313; called by muse, mutect2, varscan2
- DCAF4L1 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1199694761, COSV60786295; called by muse, mutect2, varscan2
- DDX10 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV59430926; called by muse, mutect2, varscan2
- DEFB113 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100435371; called by muse, mutect2, varscan2
- DGKE | c.179A>T p.H60L | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99400830; called by muse, mutect2
- DISC1 | c.1684A>G p.T562A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1456743930, COSV54399421; called by muse, mutect2
- DLGAP1 | c.656C>G p.S219W | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV59780164; called by muse, mutect2, varscan2
- DMBT1 | c.4965C>A p.Y1655* (on ENST00000338354 / NM_001377530.1; = p.Y898* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 95/455 reads (21%) | catalogued as COSV57532648; called by muse, mutect2, varscan2
- DNAH1 | c.1108A>G p.M370V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751414629, COSV70225861; called by muse, varscan2
- DNAH11 | c.2534C>A p.A845D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV60936980; called by muse, mutect2
- DNAH11 | c.7937T>G p.F2646C | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV60936998; called by muse, varscan2
- DNAJC18 | c.416G>C p.R139T | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758231832, COSV57414783; called by muse, mutect2, varscan2
- DNHD1 | c.12256C>T p.Q4086* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as rs1295876577, COSV54429424; called by muse, mutect2, varscan2
- DNM3 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV62452229; called by muse, mutect2, varscan2
- DOCK9 | c.5487G>C p.Q1829H (on ENST00000376460 / NM_001366676.2; = p.Q1830H on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs766104082, COSV100239562, COSV59618363; called by muse, mutect2, varscan2
- DOP1A | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); catalogued as COSV99381477; called by muse, mutect2, varscan2
- DPF1 | c.507+2T>C p.X169_splice | Splice Site (SNP) | VAF 9/84 reads (11%) | catalogued as COSV100831449; called by muse, mutect2, varscan2
- DSC2 | c.2239G>A p.D747N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV51860667; called by muse, mutect2
- DUSP26 | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV99823375; called by muse, mutect2
- EDRF1 | c.3394-2A>G p.X1132_splice (on ENST00000356792 / NM_001202438.2; = p.X1098_splice on NM_015608.2) | Splice Site (SNP) | VAF 21/93 reads (23%) | catalogued as COSV61762229; called by muse, mutect2, varscan2
- EEF1A2 | c.864G>T p.E288D | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as COSV53204529; called by muse, mutect2, varscan2
- EGR2 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV54346023, COSV54348081; called by muse, mutect2
- EIF2AK2 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.135); catalogued as COSV51794355; called by muse, mutect2
- EMC1 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV61886827; called by muse, mutect2, varscan2
- EMILIN1 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100980190; called by muse, mutect2, varscan2
- EMILIN1 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as COSV100980191; called by muse, mutect2, varscan2
- EML1 | c.2093A>G p.Y698C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV51740761; called by muse, mutect2, varscan2
- ENPP1 | c.312A>T p.E104D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.078); catalogued as COSV62929661; called by muse, mutect2, varscan2
- EPG5 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV56344050; called by muse, mutect2, varscan2
- EPHA10 | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV57621102; called by muse, mutect2, varscan2
- EPHA5 | c.2347G>C p.G783R | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56628017, COSV56649931; called by muse, mutect2, varscan2
- EPHB1 | c.1782C>G p.Y594* | Nonsense Mutation (SNP) | VAF 37/218 reads (17%) | catalogued as COSV67652943; called by muse, mutect2, varscan2
- EPHB1 | c.2244G>T p.R748S | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV67652955; called by muse, mutect2, varscan2
- EPRS1 | c.4250C>T p.S1417F | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV65096926; called by muse, mutect2
- EPS15 | c.1633G>T p.G545C | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV65540203; called by muse, mutect2, varscan2
- ESRRG | c.853C>A p.H285N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.559); catalogued as COSV63148196, COSV63159090; called by muse, varscan2
- ESS2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV52815939; called by muse, mutect2
- ESX1 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV65423807; called by muse, mutect2, varscan2
- EVI5 | c.471+2T>C p.X157_splice | Splice Site (SNP) | VAF 16/71 reads (23%) | catalogued as COSV63278555; called by muse, mutect2, varscan2
- EZH2 | c.191G>T p.R64M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57445809; called by muse, mutect2, varscan2
- EZHIP | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV57954772; called by muse, mutect2
- FAM227B | c.812G>A p.S271N | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.573); catalogued as COSV54804369; called by muse, mutect2, varscan2
- FAM3C | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as COSV63434762; called by muse, mutect2, varscan2
- FAM3C | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1384897590, COSV63434778, COSV63435821; called by muse, mutect2
- FAM47A | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); catalogued as rs745405704, COSV60493619; called by muse, mutect2, varscan2
- FAT2 | c.7921G>T p.G2641C | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55812254; called by muse, mutect2, varscan2
- FCGBP | c.7823C>T p.S2608L | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as rs1477485870; called by muse, mutect2
- FCHSD1 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99499521; called by muse, mutect2, varscan2
- FIG4 | c.2420C>G p.S807* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100019425; called by mutect2, varscan2
- FMN2 | c.3575G>T p.G1192V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.924); catalogued as COSV60414882; called by muse, mutect2, varscan2
- FOLH1 | c.1527G>T p.M509I | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57048538, COSV99922971; called by muse, varscan2
- FOXRED1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV55004905; called by muse, mutect2
- FREM2 | c.1183T>G p.Y395D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54826642; called by muse, mutect2, varscan2
- FRMD6 | c.832G>T p.G278* (on ENST00000344768 / NM_001267046.2; = p.G270* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV61086237; called by muse, mutect2, varscan2
- FRMPD1 | c.2517G>T p.R839S | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1238355264, COSV66698942, COSV66701116; called by muse, mutect2
- GABRR2 | c.633G>C p.K211N | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1201499613, COSV68764178; called by muse, mutect2
- GALNT10 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51719796; called by muse, varscan2
- GAS7 | c.643G>A p.G215S (on ENST00000432992 / NM_201433.2; = p.G75S on NM_003644.3) | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs759708568, COSV100096325, COSV60430902; called by muse, mutect2, varscan2
- GCNT4 | c.537A>T p.L179F | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV59280370; called by muse, mutect2, varscan2
- GDF10 | c.592C>G p.R198G | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1555207488; called by muse, mutect2, varscan2
- GFRA1 | c.647G>T p.C216F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62601374; called by muse, mutect2, varscan2
- GLRA2 | c.329G>T p.S110I | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); catalogued as COSV54335307; called by muse, mutect2, varscan2
- GMPR | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52471868; called by muse, mutect2, varscan2
- GOLGB1 | c.8995C>T p.Q2999* | Nonsense Mutation (SNP) | VAF 17/126 reads (13%) | catalogued as COSV61461304; called by muse, mutect2, varscan2
- GPD1L | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1201810677, COSV56988692; called by muse, mutect2, varscan2
- GPR173 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.01); catalogued as rs1447464427, COSV100212157, COSV100212465; called by muse, mutect2, varscan2
- GPR174 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985457789, COSV99337880; called by muse, mutect2, varscan2
- GPR31 | c.533A>T p.Q178L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV64761076; called by muse, mutect2, varscan2
- GSAP | c.2495A>T p.H832L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV57528025; called by muse, mutect2, varscan2
- GSX2 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100482532, COSV58842487; called by muse, mutect2, varscan2
- GTF2A2 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | catalogued as COSV51114898; called by muse, mutect2
- GTF3C3 | c.1948G>C p.D650H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.753); catalogued as COSV55830702; called by muse, mutect2, varscan2
- GTF3C5 | c.695A>T p.E232V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100565346; called by muse, mutect2
- GTPBP3 | c.1317G>T p.Q439H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV61412490; called by muse, mutect2, varscan2
- GUCA1C | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53750571, COSV53753834; called by muse, mutect2
- GUF1 | c.427-2A>T p.X143_splice | Splice Site (SNP) | VAF 32/199 reads (16%) | catalogued as COSV55781153; called by muse, mutect2, varscan2
- H2BC15 | c.377+6C>A | Splice Region (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100356948, COSV57585920; called by muse, mutect2, varscan2
- HAS2 | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58261708; called by muse, mutect2, varscan2
- HAUS4 | c.170G>T p.S57I | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV52826570; called by muse, mutect2, varscan2
- HDLBP | c.2590C>T p.Q864* | Nonsense Mutation (SNP) | VAF 18/117 reads (15%) | catalogued as COSV60491579; called by muse, mutect2, varscan2
- HEATR1 | c.4877A>T p.K1626M | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV63979647; called by muse, mutect2, varscan2
- HECW2 | c.1254T>A p.D418E | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.05); catalogued as COSV53647574; called by muse, mutect2, varscan2
- HECW2 | c.690G>C p.E230D | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV53647586; called by muse, mutect2, varscan2
- HELB | c.1423G>T p.G475W | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56071928, COSV56074112; called by muse, mutect2, varscan2
- HELQ | c.814G>C p.A272P | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV55023917; called by muse, mutect2, varscan2
- HEPH | c.2292-2A>G p.X764_splice (on ENST00000343002; = p.X497_splice on NM_014799.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 21/87 reads (24%) | catalogued as COSV57958365; called by muse, mutect2, varscan2
- HERC5 | c.568G>C p.G190R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1265373610, COSV52036871; called by muse, mutect2, varscan2
- HHAT | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs758421766, COSV54795836; called by muse, mutect2
- HHLA2 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.739); catalogued as rs1242154211, COSV56303609; called by muse, mutect2, varscan2
- HJV | c.715G>C p.E239Q (on ENST00000336751 / NM_213653.4; = p.E126Q on NM_145277.5) | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.985); catalogued as COSV60951054, COSV60952429; called by muse, mutect2
- HNF1A | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as CM971450, COSV57458690, COSV57459728, COSV57462117; called by muse, mutect2, varscan2
- HOXA3 | c.1294G>T p.G432* | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | catalogued as COSV57824854, COSV57826051; called by muse, mutect2, varscan2
- HRC | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV53255117; called by muse, mutect2, varscan2
- HUWE1 | c.2372A>T p.Q791L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV53332820; called by muse, mutect2, varscan2
- HYDIN | c.1197C>G p.F399L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV55475297; called by muse, mutect2, varscan2
- ICAM3 | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV50328193; called by muse, mutect2, varscan2
- IGLON5 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV54534245; called by muse, mutect2, varscan2
- IGLV4-60 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs1255458577, COSV101135206; called by muse, mutect2, varscan2
- IL12RB2 | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV52019818; called by muse, mutect2, varscan2
- IL33 | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV101197873; called by mutect2, varscan2
- IL6R | c.1037G>C p.R346T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV59815104; called by muse, mutect2, varscan2
- ILDR2 | c.774del p.I259Sfs*15 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | catalogued as COSV99613565; called by mutect2, pindel*, varscan2
- INSRR | c.191C>A p.T64N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.021); catalogued as COSV63870609; called by muse, mutect2, varscan2
- IPO8 | c.2954A>T p.E985V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV56239205; called by muse, mutect2, varscan2
- IRAG2 | c.4344C>G p.H1448Q (on ENST00000636465; = p.H493Q on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV57229610; called by muse, mutect2, varscan2
- IRF8 | c.505T>A p.C169S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV51900719; called by muse, mutect2, varscan2
- ITGA1 | c.1961G>T p.G654V | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50876231; called by muse, mutect2, varscan2
- ITGA8 | c.2353G>T p.A785S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65223880; called by muse, mutect2, varscan2
- ITGAE | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs761465211, COSV53988675; called by muse, mutect2, varscan2
- ITPRID1 | c.2098C>G p.L700V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs1444986775, COSV60069438; called by muse, mutect2, varscan2
- ITSN1 | c.4660G>A p.E1554K | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.618); catalogued as COSV67156734; called by muse, mutect2
- JARID2 | c.2167G>C p.V723L | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV59184543; called by muse, varscan2
- KCNA4 | c.925A>C p.I309L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV60250336; called by muse, mutect2, varscan2
- KCNJ1 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM095058, COSV60661182; called by muse, mutect2, varscan2
- KCNMB2 | c.592C>A p.H198N | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV64200358; called by muse, mutect2, varscan2
- KCNN3 | c.1848G>T p.Q616H (on ENST00000618040 / NM_001204087.1; = p.Q601H on NM_002249.6) | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV55211790; called by muse, mutect2, varscan2
- KCNN3 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.877); catalogued as COSV99677987; called by muse, mutect2
- KCNQ4 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV61271820; called by muse, mutect2
- KCNT2 | c.2742G>T p.L914F | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54061837; called by muse, mutect2, varscan2
- KEAP1 | c.1580G>T p.G527V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407570; called by muse, varscan2
- KEAP1 | c.1579G>T p.G527C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407572; called by muse, varscan2
- KIAA1109 | c.1673G>A p.G558E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52660893; called by muse, mutect2, varscan2
- KLHL1 | c.1832G>T p.S611I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64765921; called by muse, mutect2, varscan2
- KLHL41 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.048); catalogued as rs944433342, COSV52929313; called by muse, mutect2
- KLRC1 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as COSV61724708; called by muse, mutect2, varscan2
- KNG1 | c.1690C>A p.Q564K | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV53975863; called by muse, mutect2, varscan2
- KNL1 | c.3824G>C p.S1275T (on ENST00000346991 / NM_170589.5; = p.S1249T on NM_144508.5) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV61150505; called by muse, mutect2, varscan2
- KNTC1 | c.6118G>T p.D2040Y | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV61078616; called by muse, mutect2, varscan2
- KRT28 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60683370; called by muse, mutect2, varscan2
- KRTAP10-3 | c.370T>A p.C124S | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1019539404, COSV100552606; called by muse, mutect2, varscan2
- L1CAM | c.2710G>T p.G904W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62826561; called by muse, mutect2, varscan2
- LAMB4 | c.3478C>A p.R1160S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV52712612, COSV52731854; called by muse, mutect2, varscan2
- LAMC1 | c.998C>A p.A333E | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV51132032; called by muse, mutect2, varscan2
- LARP6 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV54578735; called by muse, mutect2, varscan2
- LCA5L | c.1685G>C p.R562T | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55743589; called by muse, mutect2
- LCE3E | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.835); catalogued as COSV64231475, COSV64231522; called by muse, mutect2, varscan2
- LCT | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as COSV51543456; called by muse, mutect2
- LEMD3 | c.2419C>T p.Q807* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as COSV57648090; called by muse, mutect2, varscan2
- LILRB1 | c.1013A>C p.N338T (on ENST00000427581; = p.N302T on NM_006669.6) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV61115642; called by muse, varscan2
- LRFN2 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57823167; called by muse, mutect2, varscan2
- LRP1B | c.1055A>G p.E352G | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as COSV67181905; called by muse, varscan2
- LRP1B | c.772C>G p.Q258E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV67181908, COSV67189822, COSV67243070; called by muse, mutect2, varscan2
- LRRN2 | c.1560G>C p.Q520H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV65783152; called by mutect2, varscan2
- LRRTM4 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.928); catalogued as COSV69138757; called by muse, mutect2, varscan2
- LRTM2 | c.1076A>T p.E359V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99765391; called by muse, mutect2, varscan2
- LTBP2 | c.2617A>T p.S873C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV56204271; called by muse, mutect2, varscan2
- LTBP2 | c.547A>G p.T183A | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56204279; called by muse, mutect2
- LTF | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs188531064, COSV51605268; called by muse, mutect2, varscan2
- LZTS1 | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV56115609; called by muse, mutect2, varscan2
- MANBAL | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.265); catalogued as rs747541266, COSV65311334; called by muse, mutect2, varscan2
- MAP3K11 | c.1742G>A p.R581K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV58418046; called by muse, mutect2, varscan2
- MAP3K9 | c.1429A>T p.I477F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV67119633; called by muse, mutect2, varscan2
- MAST4 | c.3839C>T p.T1280I (on ENST00000403625 / NM_001164664.2; = p.T1091I on NM_015183.3) | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55113917; called by muse, mutect2
- MC5R | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61253801; called by muse, mutect2, varscan2
- MCF2L | c.1375G>A p.E459K (on ENST00000375608; = p.E427K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV65047623; called by muse, mutect2, varscan2
- MCM7 | c.111G>T p.L37F | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV57993610; called by muse, mutect2, varscan2
- METTL17 | c.891T>G p.N297K | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV53868661; called by muse, mutect2, varscan2
- MFAP1 | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51038283; called by muse, mutect2, varscan2
- MGA | c.3788C>A p.S1263* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV54947677; called by muse, mutect2, varscan2
- MGAM | c.3010T>A p.S1004T | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV72073437; called by muse, mutect2, varscan2
- MINDY4 | c.2270T>A p.L757Q | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99518425; called by muse, mutect2, varscan2
- MKS1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs745789469, COSV58302382; called by muse, mutect2, varscan2
- MMP16 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54148701; called by muse, mutect2, varscan2
- MMP17 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.345); catalogued as COSV62178183, COSV62178195; called by muse, mutect2
- MMS22L | c.2845C>T p.L949F | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51516224; called by muse, mutect2, varscan2
- MMUT | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV51272210; called by muse, mutect2, varscan2
- MRGPRX1 | c.379C>G p.P127A | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100245925, COSV57108682; called by muse, mutect2
- MRPL16 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV55694682; called by muse, mutect2
- MTMR2 | c.1687G>A p.V563I | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs1183728500, COSV57687146; called by muse, mutect2, varscan2
- MUC16 | c.21608C>G p.S7203* | Nonsense Mutation (SNP) | VAF 34/196 reads (17%) | catalogued as COSV67440774; called by muse, mutect2, varscan2
- MUC16 | c.11027C>T p.T3676I | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.565); catalogued as COSV67440784, COSV67458513; called by muse, mutect2, varscan2
- MUC4 | c.13112C>G p.S4371* (on ENST00000463781 / NM_018406.7; = p.S135* on NM_004532.6) | Nonsense Mutation (SNP) | VAF 14/145 reads (10%) | catalogued as COSV100206651, COSV57762371; called by muse, mutect2, varscan2
- MUC5B | c.9259C>A p.P3087T | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs912573252, COSV71589669; called by muse, varscan2
- MUC5B | c.9349A>T p.R3117W | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.118); catalogued as COSV101500204; called by muse, varscan2
- MUC5B | c.9350G>T p.R3117M | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV101500205, COSV71591656; called by muse, varscan2
- MVP | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV62421232; called by muse, mutect2, varscan2
- MYBPH | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV55136911; called by muse, mutect2, varscan2
- MYO18A | c.3680A>T p.K1227M | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV62861900; called by muse, mutect2, varscan2
- MYO1B | c.2889C>G p.F963L (on ENST00000304164; = p.F905L on NM_012223.5) | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58426518; called by muse, mutect2, varscan2
- MYO5A | c.3458C>G p.S1153* | Nonsense Mutation (SNP) | VAF 29/143 reads (20%) | catalogued as COSV62556103; called by muse, mutect2, varscan2
- MYO5C | c.3235G>T p.E1079* | Nonsense Mutation (SNP) | VAF 48/152 reads (32%) | catalogued as COSV55902110; called by muse, mutect2, varscan2
- MYT1L | c.1266G>T p.E422D | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.183); catalogued as COSV67706236; called by muse, mutect2, varscan2
- NAALADL2 | c.838A>T p.S280C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.319); catalogued as COSV69152959; called by muse, mutect2, varscan2
- NAALADL2 | c.1469C>G p.T490S | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as rs778343683, COSV69152979; called by muse, mutect2, varscan2
- NALCN | c.2448G>T p.E816D | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV51914833; called by muse, mutect2, varscan2
- NALCN | c.945C>A p.N315K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51914852, COSV51930921; called by muse, mutect2, varscan2
- NAV3 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs780201858, COSV57058784; called by muse, mutect2, varscan2
- NBL1 | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99229403; called by muse, mutect2
- NBPF1 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 20/534 reads (4%) | catalogued as COSV101236472, COSV101236737; called by muse, mutect2
- NDC80 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV55246677, COSV55248602; called by muse, mutect2, varscan2
- NDEL1 | c.807A>T p.K269N | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100232853; called by muse, mutect2, varscan2
- NDFIP2 | c.735G>T p.W245C | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54526470; called by muse, varscan2
- NEB | c.4955C>T p.S1652L | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.149); catalogued as COSV50805867; called by muse, mutect2, varscan2
- NEXMIF | c.969C>A p.D323E | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs774081399, COSV50021480; called by muse, mutect2, varscan2
- NKAIN2 | c.39C>G p.I13M | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV63641139; called by muse, mutect2, varscan2
- NLRC4 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs774266949, COSV61590922; called by muse, mutect2, varscan2
- NOX4 | c.1284C>G p.C428W | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54445848, COSV99630202; called by muse, mutect2, varscan2
- NPC1L1 | c.606G>T p.W202C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1315210690, COSV56922068; called by muse, varscan2
- NR2E1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV64561211, COSV64561259; called by muse, mutect2
- NR2E1 | c.502C>G p.H168D | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV64561217; called by muse, mutect2, varscan2
- NR5A2 | c.183G>C p.Q61H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV52644180; called by muse, mutect2, varscan2
- NRXN1 | c.3272C>T p.S1091L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58434140; called by muse, mutect2
- OBSCN | c.17887G>T p.E5963* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV52735428; called by muse, mutect2, varscan2
- OGDHL | c.8A>T p.Q3L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.051); catalogued as COSV65100568; called by muse, mutect2
- OLR1 | c.775G>C p.A259P | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV58870749, COSV58870834; called by muse, mutect2, varscan2
- OPA1 | c.1211A>T p.D404V (on ENST00000361510 / NM_130837.3; = p.D349V on NM_015560.3) | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62478620; called by muse, mutect2
- OR10A2 | c.667A>G p.K223E | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV56298575; called by muse, varscan2
- OR10A7 | c.265A>T p.R89W | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV58279562; called by muse, mutect2, varscan2
- OR10C1 | c.802G>A p.D268N (on ENST00000622521; = p.D266N on NM_013941.3) | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV65822153, COSV65822361; called by muse, mutect2, varscan2
- OR10G2 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.921); catalogued as COSV101606941; called by muse, mutect2, varscan2
- OR10G2 | c.814C>A p.P272T | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.065); catalogued as COSV101606942; called by muse, mutect2, varscan2
- OR10X1 | c.398T>C p.L133S | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV63766860; called by muse, mutect2, varscan2
- OR11H1 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.46); catalogued as COSV99421720; called by mutect2, varscan2
- OR2M3 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 144/534 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs143959338; called by muse, mutect2, varscan2
- OR2M5 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 47/442 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747013982, COSV63545534; called by muse, mutect2, varscan2
- OR4C15 | c.707C>A p.P236Q (on ENST00000314644; = p.P182Q on NM_001001920.2) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV58950833; called by muse, mutect2, varscan2
- OR4C15 | c.968T>C p.M323T (on ENST00000314644; = p.M269T on NM_001001920.2) | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.03); catalogued as COSV58950845; called by muse, mutect2, varscan2
- OR4C16 | c.232A>G p.R78G | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV58940395; called by muse, mutect2, varscan2
- OR4C3 | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV60583053; called by muse, mutect2, varscan2
- OR4C6 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV58602288; called by muse, mutect2, varscan2
- OR4D6 | c.548A>T p.Q183L | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV55658825; called by muse, mutect2, varscan2
- OR4M1 | c.707A>T p.N236I | Missense Mutation (SNP) | VAF 54/576 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV60059261; called by muse, mutect2
- OR4N5 | c.698A>G p.K233R | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV100374073; called by muse, mutect2, varscan2
- OR5B2 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs369296397; called by muse, mutect2, varscan2
- OR5H1 | c.548C>A p.P183Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.993); catalogued as rs1198602863, COSV63401597; called by muse, mutect2
- OR5L2 | c.621G>T p.E207D | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV65723292, COSV65724478; called by muse, mutect2, varscan2
- OR6N2 | c.882C>G p.N294K | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59409881; called by muse, mutect2, varscan2
- OR7A5 | c.307T>A p.F103I | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV59233998; called by muse, mutect2, varscan2
- OR8J1 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.059); catalogued as rs764474970, COSV100274929; called by muse, mutect2, varscan2
- OR9A4 | c.756C>A p.Y252* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | catalogued as COSV71884906, COSV71885528; called by muse, mutect2, varscan2
- OSBPL1A | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60194703; called by muse, mutect2, varscan2
- OSBPL5 | c.1810-1G>T p.X604_splice | Splice Site (SNP) | VAF 8/39 reads (21%) | catalogued as COSV55139017; called by muse, mutect2, varscan2
- OXTR | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.026); catalogued as COSV57478197; called by muse, mutect2
- P2RX7 | c.482C>A p.T161N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55853043; called by muse, mutect2
- PALB2 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV55161817; called by muse, mutect2, varscan2
- PARD6B | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV65404033; called by muse, mutect2
- PARP10 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV57296513; called by muse, mutect2, varscan2
- PASD1 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV64853822; called by muse, mutect2, varscan2
- PATJ | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100333684; called by muse, mutect2, varscan2
- PATJ | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548467170, COSV100333685; called by muse, mutect2, varscan2
- PCDHAC1 | c.1424G>T p.G475V | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV53835795, COSV53865472; called by muse, mutect2, varscan2
- PCDHB7 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as rs781942345, COSV50753489; called by muse, mutect2, varscan2
- PCLO | c.6502G>T p.E2168* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as COSV61612516; called by muse, varscan2
- PCLO | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 115/452 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV61612548; called by muse, varscan2
- PCLO | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 43/368 reads (12%) | catalogued as COSV61612566; called by muse, mutect2, varscan2
- PCNX1 | c.3150+1G>T p.X1050_splice | Splice Site (SNP) | VAF 38/155 reads (25%) | catalogued as COSV53088361; called by muse, mutect2, varscan2
- PDE1A | c.478T>C p.W160R | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV59513028; called by muse, mutect2
- PDE4DIP | c.3163G>C p.E1055Q | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57671501; called by muse, mutect2
- PDIA3 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.301); catalogued as rs772223861, COSV55854435; called by muse, mutect2, varscan2
- PDIA3 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55854452; called by muse, mutect2, varscan2
- PDS5B | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.311); catalogued as COSV59722678; called by muse, mutect2, varscan2
- PGF | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV53124406; called by muse, mutect2, varscan2
- PGM5 | c.1453G>A p.V485M | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67166697; called by muse, mutect2
- PIGT | c.831G>C p.E277D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.096); catalogued as COSV54124862; called by muse, mutect2, varscan2
- PIK3CA | c.32G>T p.W11L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55873743, COSV55891755; called by muse, mutect2, varscan2
- PIK3R1 | c.1020-1G>T p.X340_splice (on ENST00000521381 / NM_181523.3; = p.X70_splice on NM_181504.4) | Splice Site (SNP) | VAF 11/56 reads (20%) | catalogued as COSV57122764; called by muse, mutect2, varscan2
- PLA2G4A | c.2210G>T p.R737I | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as COSV66551457; called by muse, mutect2, varscan2
- PLAAT5 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57136024; called by muse, mutect2, varscan2
- PLB1 | c.1987C>G p.R663G | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV59818597, COSV59823188; called by muse, mutect2, varscan2
- PLCB2 | c.3161G>A p.R1054Q | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs760283955, COSV53030434; called by muse, mutect2
- PLCE1 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV53335140; called by muse, mutect2, varscan2
- PLCG2 | c.2984C>T p.S995L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100842152; called by muse, mutect2, varscan2
- PLEC | c.11052G>C p.E3684D (on ENST00000322810 / NM_201380.4; = p.E3574D on NM_000445.5) | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.551); catalogued as COSV59598781; called by muse, mutect2, varscan2
- PLEKHH2 | c.2437A>C p.T813P | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV56749133; called by muse, mutect2, varscan2
- PLIN2 | c.1167G>T p.M389I | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99438814; called by muse, mutect2, varscan2
- PLPP4 | c.208A>G p.K70E | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV64826406; called by muse, mutect2, varscan2
- PLXNB2 | c.1361A>C p.Y454S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63779905; called by muse, mutect2, varscan2
- POC5 | c.602C>G p.A201G (on ENST00000428202 / NM_001099271.2; = p.A176G on NM_152408.2) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV100700694; called by muse, mutect2, varscan2
- POGLUT2 | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65682678; called by muse, mutect2, varscan2
- POLA1 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV66883264; called by muse, mutect2, varscan2
- POPDC2 | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.124); catalogued as COSV51739648; called by muse, mutect2, varscan2
- PPEF1 | c.1618T>C p.Y540H | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62994993; called by muse, mutect2, varscan2
- PPIG | c.2008G>C p.D670H | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as COSV53640668; called by muse, mutect2
- PPIH | c.337-2A>T p.X113_splice | Splice Site (SNP) | VAF 25/116 reads (22%) | catalogued as COSV59245575; called by muse, mutect2, varscan2
- PPM1D | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV59954091; called by muse, varscan2
- PPP1R32 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV58543905; called by muse, mutect2
- PRDM9 | c.2399G>T p.G800V | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57001682, COSV57003614; called by muse, varscan2
- PREX2 | c.484T>A p.L162M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV55748446; called by muse, mutect2, varscan2
- PREX2 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55748462; called by muse, mutect2
- PRKCSH | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 23/105 reads (22%) | catalogued as COSV52950071; called by muse, mutect2, varscan2
- PROC | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV52164507, COSV99300907; called by muse, mutect2
- PRODH2 | c.1499G>T p.R500L (on ENST00000301175; = p.R424L on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56558027; called by muse, mutect2, varscan2
- PRTG | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs961490937, COSV66836540; called by muse, mutect2, varscan2
- PTCHD3 | c.974T>A p.L325Q | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.131); catalogued as COSV71256238; called by muse, mutect2, varscan2
- PTGER3 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as rs774915619, COSV100138593; called by muse, mutect2, varscan2
- PTMA | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1379602206, COSV58187679; called by muse, mutect2
- PTPN3 | c.1997A>G p.K666R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52701542; called by muse, mutect2
- PTPRD | c.3481C>A p.P1161T | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV61925074; called by muse, mutect2, varscan2
- PUM1 | c.426G>T p.M142I | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV57080916; called by muse, mutect2, varscan2
- PXDNL | c.389A>G p.H130R | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV62476310; called by muse, mutect2, varscan2
- RAB5C | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs761919578, COSV60524000; called by muse, mutect2, varscan2
- RAD21 | c.1880G>A p.R627K | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.946); catalogued as COSV52055837; called by muse, mutect2, varscan2
- RAD51AP2 | c.2127G>C p.Q709H | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV101208265, COSV67587204; called by muse, mutect2, varscan2
- RAD54L | c.1447C>A p.P483T | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV58438752, COSV58440691; called by muse, mutect2
- RADIL | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs774168165, COSV101271330; called by muse, mutect2, varscan2
- RAPGEF4 | c.1855C>A p.L619I | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.303); catalogued as COSV51378937; called by muse, mutect2, varscan2
- RAPGEF6 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as COSV99725971; called by muse, mutect2, varscan2
- RDH11 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV101191404; called by muse, mutect2, varscan2
- REG3G | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV55447692; called by muse, mutect2, varscan2
- REG3G | c.283A>T p.I95F | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.079); catalogued as COSV55447701; called by muse, varscan2
- REV3L | c.8635G>C p.E2879Q | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100725229, COSV62614366; called by muse, mutect2
- REV3L | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV62614383; called by muse, mutect2
- RIOK3 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.067); catalogued as COSV59771874; called by muse, mutect2, varscan2
- RNASET2 | c.567+1G>T p.X189_splice | Splice Site (SNP) | VAF 20/111 reads (18%) | catalogued as COSV50351069; called by muse, mutect2, varscan2
- RNF157 | c.1232G>A p.R411K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.718); catalogued as COSV53941481; called by muse, mutect2, varscan2
- RNF180 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV56959659; called by muse, mutect2
- RNF213 | c.2992T>C p.C998R | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149136204; called by muse, mutect2, varscan2
- RORB | c.700C>T p.H234Y (on ENST00000396204 / NM_001365023.1; = p.H223Y on NM_006914.4) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.434); catalogued as COSV65332342; called by muse, mutect2, varscan2
- RTL4 | c.621C>G p.D207E | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61205569; called by muse, varscan2
- RTN1 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as COSV50718415; called by muse, mutect2, varscan2
- RYR1 | c.10712G>T p.W3571L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62087118; called by muse, mutect2, varscan2
- RYR2 | c.3823G>C p.G1275R | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV63657293, COSV63684336; called by muse, mutect2, varscan2
- RYR2 | c.6980G>T p.R2327M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100768916, COSV63657304; called by muse, mutect2, varscan2
- RYR2 | c.9584T>C p.L3195P | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV63657317; called by muse, mutect2, varscan2
- SALL4 | c.2742G>T p.K914N | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53849492; called by muse, mutect2
- SAMM50 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63109260; called by muse, mutect2, varscan2
- SCRN2 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV51634736, COSV99274393; called by muse, mutect2, varscan2
- SDK1 | c.3473C>A p.P1158H | Missense Mutation (SNP) | VAF 27/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67354575, COSV67368942; called by muse, mutect2, varscan2
- SEC23IP | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV64830582; called by muse, mutect2, varscan2
- SEL1L2 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV53147303; called by muse, mutect2, varscan2
- SEMA3A | c.2185G>T p.D729Y | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs1222440433, COSV54860221, COSV99546765; called by muse, mutect2, varscan2
- SEMA6A | c.2691G>C p.Q897H | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1286594588, COSV56708981; called by muse, mutect2, varscan2
- SEMA6D | c.1947A>T p.E649D (on ENST00000316364 / NM_153618.2; = p.E587D on NM_020858.2) | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV60371874, COSV60373482, COSV60380284; called by muse, mutect2, varscan2
- SERPINA10 | c.338T>A p.M113K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV56227305; called by muse, mutect2, varscan2
- SERPINB6 | c.785C>T p.T262M (on ENST00000612421 / NM_001271823.2; = p.T243M on NM_004568.6) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as rs776896710, COSV59564702; called by muse, varscan2
- SERPINC1 | c.371T>A p.L124Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100875026; called by muse, mutect2, varscan2
- SFRP4 | c.980G>T p.S327I | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV71412170; called by muse, mutect2
- SGO2 | c.310-1G>C p.X104_splice | Splice Site (SNP) | VAF 24/145 reads (17%) | catalogued as rs1396459005, COSV63413664; called by muse, mutect2, varscan2
- SH2D1A | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100758349, COSV63578461, COSV63579904; called by muse, mutect2, varscan2
- SHF | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV52049135; called by muse, mutect2, varscan2
- SHISAL1 | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV66987363; called by muse, mutect2, varscan2
- SIN3A | c.3671G>A p.R1224H | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs148486660; called by muse, mutect2, varscan2
- SIRPB1 | c.1182G>T p.W394C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV53537189; called by muse, mutect2
- SIRPB2 | c.606G>T p.E202D | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63122743; called by muse, mutect2, varscan2
- SLC22A8 | c.1024T>C p.Y342H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60323298; called by muse, mutect2, varscan2
- SLC23A3 | c.900G>T p.W300C (on ENST00000409878 / NM_001144889.2; = p.G268V on NM_144712.5) | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV55405413, COSV55409016; called by muse, mutect2
- SLC35F3 | c.373G>A p.E125K (on ENST00000366617 / NM_001300845.1; = p.E194K on NM_173508.4) | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV64018010; called by muse, mutect2, varscan2
- SLC39A12 | c.9C>A p.F3L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV101069962; called by muse, mutect2, varscan2
- SLC3A2 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV58602725; called by muse, mutect2
- SLC45A2 | c.1164G>C p.Q388H | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV56869305; called by muse, mutect2, varscan2
- SLC52A3 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as COSV54076460; called by muse, mutect2, varscan2
- SLC5A1 | c.491C>A p.S164* | Nonsense Mutation (SNP) | VAF 42/237 reads (18%) | catalogued as COSV56682874, COSV56684233; called by muse, mutect2, varscan2
- SLC6A5 | c.1666A>T p.R556W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV54222953; called by muse, mutect2, varscan2
- SLCO2B1 | c.2085G>C p.L695F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.789); catalogued as COSV56932594; called by muse, mutect2, varscan2
- SLPI | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV100619753; called by muse, mutect2, varscan2
- SMARCA2 | c.2502A>G p.I834M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as COSV61804298; called by muse, mutect2, varscan2
- SMPD4 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1200398429; called by muse, mutect2, varscan2
- SNAP91 | c.2216C>G p.S739* | Nonsense Mutation (SNP) | VAF 5/92 reads (5%) | catalogued as COSV52114136; called by muse, mutect2
- SOS2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99365221; called by muse, mutect2
- SPATA31D1 | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 43/291 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.082); catalogued as rs373293574, COSV61201629; called by muse, mutect2, varscan2
- SPG11 | c.6079C>T p.Q2027* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV55990213; called by muse, mutect2, varscan2
- SPICE1 | c.1812G>T p.W604C | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV55617667, COSV99871155; called by muse, mutect2, varscan2
- SPPL2C | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61291629; called by muse, mutect2, varscan2
- SRBD1 | c.2548G>T p.V850F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV55395267; called by muse, mutect2, varscan2
- SRPK3 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV54205787; called by muse, mutect2, varscan2
- STIP1 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 32/239 reads (13%) | catalogued as COSV59438148; called by muse, mutect2, varscan2
- STK26 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61228686; called by muse, mutect2, varscan2
- STX11 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV100845476, COSV62448952; called by muse, varscan2
- SULF1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52671957; called by muse, mutect2
- SYCP1 | c.685C>A p.R229S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65694118, COSV65698105; called by muse, mutect2, varscan2
- SYCP2L | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51649392; called by muse, mutect2
- TAAR1 | c.828T>A p.F276L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.267); catalogued as COSV99257521; called by muse, mutect2, varscan2
- TAOK3 | c.1626G>C p.K542N | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV66824553; called by muse, mutect2
- TBC1D22A | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781476335, COSV61434796; called by muse, mutect2, varscan2
- TBCD | c.2824C>T p.R942* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as rs759557110, COSV62797206; called by muse, mutect2, varscan2
- TBX21 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1301731556, COSV51594781, COSV51598034; called by muse, mutect2, varscan2
- TBX22 | c.1219A>T p.M407L | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV64784790; called by muse, mutect2, varscan2
- TBX4 | c.1254C>A p.N418K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV53604878; called by muse, mutect2, varscan2
- TCEA3 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs760310434, COSV65840696; called by muse, mutect2
- TCERG1 | c.1249G>C p.V417L | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57033443; called by muse, mutect2, varscan2
- TCHHL1 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.38); catalogued as COSV64284708; called by muse, mutect2
- TDRD1 | c.3415A>G p.R1139G | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV52586937; called by muse, mutect2
- TECRL | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV67085198; called by muse, mutect2, varscan2
- TEX30 | c.431G>C p.R144T | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101051987; called by mutect2, varscan2
- TGM6 | c.345C>G p.S115R | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV52477033; called by muse, mutect2
- THAP12 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.469); catalogued as COSV52609071; called by muse, mutect2, varscan2
- THSD7A | c.2428G>T p.G810W | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70259431; called by muse, mutect2
- TIGD3 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52887658; called by mutect2, varscan2
- TJP1 | c.2981C>T p.S994L | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs751977843, COSV62038973; called by muse, mutect2
- TMC4 | c.148C>T p.R50W (on ENST00000617472 / NM_001145303.3; = p.R44W on NM_144686.4) | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs200450643; called by muse, mutect2
- TMED10 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV57846709; called by muse, mutect2, varscan2
- TMED7 | c.85C>G p.P29A | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99143256; called by muse, mutect2
- TMEM184A | c.1194G>C p.K398N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.199); catalogued as COSV52471715; called by muse, mutect2, varscan2
- TMEM30A | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.444); catalogued as COSV57874502; called by muse, mutect2
- TMEM51 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV101051504; called by muse, mutect2, varscan2
- TMPRSS11F | c.164-1G>T p.X55_splice | Splice Site (SNP) | VAF 19/80 reads (24%) | catalogued as COSV62464153; called by muse, mutect2, varscan2
- TMPRSS12 | c.944A>G p.E315G | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV68255722; called by muse, mutect2, varscan2
- TMPRSS15 | c.2834T>A p.M945K | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV53034063; called by muse, mutect2, varscan2
- TNFRSF9 | c.430A>T p.K144* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV66348675; called by muse, mutect2, varscan2
- TNNI3K | c.2151G>A p.M717I | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53945402, COSV99037969; called by muse, mutect2
- TNR | c.4048G>T p.G1350W | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54867634; called by muse, mutect2, varscan2
- TNR | c.3388C>T p.R1130W | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs755238671, COSV54867651, COSV54909180; called by muse, mutect2
- TNR | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV54867669; called by muse, mutect2, varscan2
- TNR | c.644T>A p.V215E | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.565); catalogued as COSV54867677; called by muse, mutect2
- TRHR | c.1025C>A p.T342K | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV61232627, COSV61236686; called by muse, mutect2, varscan2
- TRIO | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV100710005, COSV100710990, COSV60076707; called by muse, mutect2
- TRMT10C | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV59305035; called by muse, mutect2, varscan2
- TRPM6 | c.3715G>T p.A1239S | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV62502085, COSV62502646; called by muse, mutect2
- TTN | c.92003C>G p.S30668C (on ENST00000591111; = p.S23244C on NM_003319.4) | Missense Mutation (SNP) | VAF 34/396 reads (9%) | PolyPhen possibly damaging (0.799); catalogued as COSV59861493; called by muse, mutect2
- TTN | c.64677A>T p.K21559N (on ENST00000591111; = p.K14135N on NM_003319.4) | Missense Mutation (SNP) | VAF 76/349 reads (22%) | PolyPhen possibly damaging (0.801); catalogued as COSV59861529; called by muse, mutect2, varscan2
- TTN | c.46225C>T p.P15409S (on ENST00000591111; = p.P7985S on NM_003319.4) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | PolyPhen possibly damaging (0.755); catalogued as COSV59861566; called by muse, mutect2, varscan2
- TYRP1 | c.1153A>G p.N385D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66357668; called by muse, mutect2
- U2SURP | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.018); catalogued as COSV67529854; called by muse, mutect2
- UBAP1 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs776060440, COSV99902995; called by muse, mutect2, varscan2
- UBE3A | c.2348A>G p.D783G | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV51660448; called by muse, mutect2, varscan2
- UBE3D | c.684T>A p.Y228* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV52751271; called by muse, varscan2
- UNC45B | c.653T>A p.L218Q | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52091624; called by muse, mutect2, varscan2
- UNC79 | c.1150G>A p.V384I (on ENST00000393151 / NM_001346218.2; = p.V207I on NM_020818.5) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.987); catalogued as COSV56371750; called by muse, mutect2, varscan2
- UNC79 | c.5381C>T p.A1794V (on ENST00000393151 / NM_001346218.2; = p.A1617V on NM_020818.5) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV56371773; called by muse, mutect2, varscan2
- USP26 | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100896590; called by muse, mutect2, varscan2
- USP8 | c.3003G>A p.W1001* | Nonsense Mutation (SNP) | VAF 31/101 reads (31%) | catalogued as COSV56161793; called by muse, mutect2, varscan2
- UTP14C | c.2018A>T p.N673I | Missense Mutation (SNP) | VAF 90/344 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73000530; called by muse, mutect2, varscan2
- VAV2 | c.2453T>C p.I818T (on ENST00000371850 / NM_001134398.2; = p.I779T on NM_003371.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV64079992; called by mutect2, varscan2
- VCAN | c.666G>T p.M222I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54095610; called by muse, mutect2, varscan2
- VPS13C | c.4095G>T p.R1365S (on ENST00000644861 / NM_020821.3; = p.R1322S on NM_017684.5) | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV51119908; called by muse, mutect2, varscan2
- VRK3 | c.596A>T p.K199M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV57464177; called by muse, mutect2, varscan2
- WASHC5 | c.3091A>G p.I1031V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.833); catalogued as rs753799341, COSV59193659; called by muse, mutect2, varscan2
- WDCP | c.526G>C p.G176R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54591318; called by muse, mutect2, varscan2
- WDFY3 | c.6930G>A p.W2310* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV55692121; called by muse, mutect2, varscan2
- WDR1 | c.1552G>A p.V518I (on ENST00000382452; = p.V378I on NM_005112.5) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.384); catalogued as rs1255779655, COSV101221086; called by muse, mutect2
- WDR49 | c.1252C>G p.H418D (on ENST00000308378 / NM_001366158.1; = p.H759D on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100392897, COSV57701268; called by muse, mutect2, varscan2
- WDR64 | c.1390A>C p.N464H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63792301; called by muse, mutect2, varscan2
- WNT8A | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV64231850; called by muse, mutect2, varscan2
- ZC3H12C | c.2107C>T p.L703F | Missense Mutation (SNP) | VAF 71/266 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.206); catalogued as COSV53706122; called by muse, mutect2, varscan2
- ZC3H4 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs773853787, COSV53410113, COSV99452497; called by muse, mutect2, varscan2
- ZDHHC15 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV64900414, COSV64902137; called by muse, mutect2, varscan2
- ZEB1 | c.56A>G p.N19S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.257); catalogued as COSV58035397; called by muse, mutect2, varscan2
- ZFHX4 | c.1882C>G p.L628V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50478691; called by muse, mutect2, varscan2
- ZFP82 | c.635A>G p.H212R | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV67564469; called by muse, mutect2, varscan2
- ZFYVE21 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs767572586, COSV53694132; called by muse, mutect2, varscan2
- ZMIZ1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV57888863; called by muse, mutect2, varscan2
- ZNF25 | c.920G>T p.S307I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56921537; called by muse, mutect2, varscan2
- ZNF292 | c.6382C>G p.Q2128E | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV60534988; called by muse, mutect2, varscan2
- ZNF460 | c.1311G>C p.R437S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100828078, COSV64415268; called by muse, mutect2, varscan2
- ZNF510 | c.1267C>G p.Q423E | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV56296042; called by muse, mutect2, varscan2
- ZNF570 | c.1259G>T p.R420M | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57577940; called by muse, mutect2, varscan2
- ZNF70 | c.1097G>A p.C366Y | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59531970; called by muse, mutect2, varscan2
- ZNF781 | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV62200107; called by muse, mutect2, varscan2
- ZNF79 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV61070229; called by muse, mutect2
- ZNF804B | c.2857A>G p.S953G | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1170775545, COSV60814486; called by muse, mutect2, varscan2
- ZSCAN5A | c.581G>T p.R194M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as COSV54223291, COSV99570408; called by muse, mutect2, varscan2
- ZYG11B | c.2186A>G p.H729R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV53749548; called by muse, mutect2, varscan2
- ABCB11 | c.1379del p.G460Efs*20 | Frame Shift Del (DEL) | VAF 31/196 reads (16%) | called by mutect2, pindel, varscan2
- ANXA11 | c.377C>G p.A126G | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- ASAH2 | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- BAZ1B | c.2634del p.K878Nfs*19 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | called by mutect2, pindel, varscan2
- BMP5 | c.885del p.Q295Hfs*21 | Frame Shift Del (DEL) | VAF 21/136 reads (15%) | called by mutect2, pindel, varscan2
- CACNA1B | c.5665del p.L1889Cfs*5 | Frame Shift Del (DEL) | VAF 13/109 reads (12%) | called by mutect2, pindel, varscan2
- CDH10 | c.976_977del p.Q326Gfs*13 | Frame Shift Del (DEL) | VAF 68/310 reads (22%) | called by pindel, varscan2
- CNBD1 | c.329dup p.N110Kfs*17 | Frame Shift Ins (INS) | VAF 12/102 reads (12%) | called by mutect2, varscan2
- CSDE1 | c.2352del p.F785Lfs*23 (on ENST00000358528 / NM_001007553.3; = p.F754Lfs*23 on NM_007158.6) | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | called by mutect2, pindel, varscan2
- HEATR1 | c.5485dup p.T1829Nfs*6 | Frame Shift Ins (INS) | VAF 18/132 reads (14%) | called by mutect2, varscan2
- HEATR6 | c.1392del p.T465Hfs*2 | Frame Shift Del (DEL) | VAF 21/86 reads (24%) | called by mutect2, varscan2
- IGKV1D-12 | c.8T>C p.M3T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IGKV6D-41 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KCTD5 | c.603_604del p.V204Gfs*74 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by mutect2, pindel, varscan2
- KLC1 | c.869del p.G290Afs*11 | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | called by mutect2, pindel, varscan2
- KRT7 | c.225del p.L76Cfs*122 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- LAMTOR2 | c.168_175del p.Y56* | Frame Shift Del (DEL) | VAF 19/153 reads (12%) | called by mutect2, pindel
- LPA | c.13del p.E5Kfs*10 | Frame Shift Del (DEL) | VAF 18/122 reads (15%) | called by mutect2, pindel, varscan2
- MSGN1 | c.205T>A p.C69S | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PCDHA9 | c.107del p.P36Rfs*42 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | called by mutect2, varscan2
- RBP3 | c.2986C>A p.P996T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SCN11A | c.3602del p.S1201Lfs*15 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- SPEF2 | c.933del p.R312Gfs*4 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- SPTLC1 | c.1386del p.T463Pfs*5 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel*, varscan2
- SYNE1 | c.2419del p.L807Ffs*8 (on ENST00000367255 / NM_182961.4; = p.L814Ffs*8 on NM_033071.3) | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by pindel, varscan2
- SYNE2 | c.2049dup p.D684* | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | called by mutect2, pindel
- SYT3 | c.1123del p.A375Pfs*76 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- TFB1M | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- TMEM63B | c.1942+2_1942+13del p.X648_splice | Splice Site (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel
- TRAV10 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ADAM7 | c.2160G>A p.E720= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV51534321; called by muse, mutect2
- ADAMTS12 | c.3309G>A p.E1103= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV100710454, COSV61254394; called by muse, mutect2, varscan2
- ADAMTS12 | c.225C>T p.I75= | Silent (SNP) | VAF 112/292 reads (38%) | catalogued as COSV61254404; called by muse, mutect2, varscan2
- ADGRV1 | c.11931A>T p.A3977= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV67977321; called by muse, mutect2, varscan2
- AGBL2 | c.1134G>T p.T378= | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as COSV54089706; called by muse, mutect2, varscan2
- AKAP12 | c.168A>G p.L56= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs763642797, COSV53569667; called by mutect2, varscan2
- ANKRD11 | c.6351G>T p.P2117= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV56353509; called by muse, mutect2, varscan2
- ANKRD11 | c.1686C>G p.V562= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV56353533; called by muse, mutect2, varscan2
- ANO4 | c.2211C>A p.A737= (on ENST00000392977 / NM_001286615.2; = p.A702= on NM_178826.4) | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV54583511, COSV54608820; called by muse, mutect2, varscan2
- ARID3B | c.708C>T p.I236= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV60556291; called by muse, mutect2, varscan2
- ARRDC2 | c.711G>T p.R237= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1449473629, COSV99716648; called by muse, mutect2, varscan2
- ASH1L | c.4527T>C p.S1509= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV64204916; called by muse, mutect2, varscan2
- ASTN1 | c.2211G>A p.K737= | Silent (SNP) | VAF 56/255 reads (22%) | catalogued as COSV56060462, COSV99923621; called by muse, mutect2, varscan2
- ATP13A4 | c.753C>T p.L251= | Silent (SNP) | VAF 10/165 reads (6%) | catalogued as COSV55065410, COSV55069576; called by muse, mutect2
- ATP2B4 | c.162C>G p.L54= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as COSV58173846; called by muse, mutect2, varscan2
- ATP4A | c.2214G>A p.K738= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV52865093; called by muse, mutect2, varscan2
- BMP2 | c.465A>G p.E155= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV66576831; called by muse, mutect2, varscan2
- C4BPB | c.582C>A p.I194= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV54690608; called by muse, mutect2, varscan2
- CACNA1E | c.4524G>A p.L1508= | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as rs966711307, COSV62380967; called by muse, varscan2
- CACNA2D1 | c.633C>G p.A211= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV62371397; called by muse, mutect2, varscan2
- CADPS | c.3675C>A p.P1225= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV51865334; called by mutect2, varscan2
- CCDC83 | c.1125G>A p.V375= (on ENST00000342404 / NM_001286159.2; = p.V406= on NM_173556.5) | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as COSV99721585; called by muse, mutect2
- CDCA7 | c.825G>A p.Q275= (on ENST00000347703 / NM_145810.3; = p.Q354= on NM_031942.5) | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV60719746; called by muse, mutect2, varscan2
- CDH11 | c.1041A>T p.V347= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV51750155; called by muse, mutect2, varscan2
- CDH9 | c.1275T>A p.T425= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as COSV50250735; called by muse, mutect2, varscan2
- CNTN3 | c.156A>C p.A52= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV55161757; called by muse, mutect2, varscan2
- CNTN5 | c.1962C>A p.T654= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV54275089; called by muse, mutect2, varscan2
- COL24A1 | c.1380C>T p.P460= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV65300979; called by muse, mutect2, varscan2
- COL9A1 | c.222C>A p.I74= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV61827805; called by muse, mutect2, varscan2
- COLEC11 | c.219A>G p.K73= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV52591199; called by muse, mutect2, varscan2
- CRISP2 | c.651G>A p.L217= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV59253065; called by muse, mutect2, varscan2
- CRISP3 | c.735T>C p.S245= (on ENST00000371159 / NM_001368123.1; = p.S227= on NM_006061.4) | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs765025934, COSV53818756; called by muse, mutect2, varscan2
- CSF2RB | c.2323C>A p.R775= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV53255186; called by muse, mutect2, varscan2
- CSMD3 | c.1437T>C p.I479= (on ENST00000297405 / NM_001363185.1; = p.I375= on NM_052900.3) | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV52090562; called by muse, mutect2, varscan2
- DOCK3 | c.5197C>T p.L1733= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV56500189; called by muse, mutect2, varscan2
- DPY19L3 | c.528A>T p.I176= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV60474386; called by muse, mutect2, varscan2
- EGFR | c.1956G>T p.G652= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV51765425; called by muse, mutect2, varscan2
- EPHA10 | c.777C>T p.D259= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1041243769, COSV57625516; called by muse, mutect2, varscan2
- ERMARD | c.1770G>A p.L590= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV64647484; called by muse, mutect2
- ESX1 | c.456G>A p.Q152= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV65423815; called by muse, mutect2, varscan2
- FAT3 | c.1689T>C p.N563= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as COSV53070731; called by muse, mutect2
- FAT3 | c.5559G>A p.V1853= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1030736548, COSV53070758; called by muse, mutect2, varscan2
- FBXO38 | c.2460G>T p.L820= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV57025461; called by muse, mutect2, varscan2
- FBXO44 | c.279C>T p.F93= | Silent (SNP) | VAF 45/151 reads (30%) | catalogued as rs1468111299, COSV99278815, COSV99278977; called by muse, mutect2, varscan2
- FCGR2A | c.39C>T p.P13= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs745350800, COSV54836901; called by muse, mutect2, varscan2
- FCRLB | c.207C>G p.P69= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as COSV61059190; called by muse, mutect2, varscan2
- FFAR4 | c.675C>T p.I225= | Silent (SNP) | VAF 20/192 reads (10%) | catalogued as COSV65178404; called by muse, mutect2
- FGD6 | c.2229C>T p.L743= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV59689851; called by muse, mutect2
- FREM2 | c.3822A>G p.E1274= | Silent (SNP) | VAF 28/183 reads (15%) | catalogued as COSV54826661; called by muse, mutect2, varscan2
- GABBR1 | c.1983C>T p.F661= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs757538966, COSV63540632; called by muse, mutect2, varscan2
- GALNT6 | c.1233C>A p.T411= | Silent (SNP) | VAF 29/235 reads (12%) | catalogued as COSV62541529; called by muse, mutect2, varscan2
- GGA1 | c.1230G>T p.A410= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV57328590; called by muse, mutect2, varscan2
- GJA1 | c.51C>T p.Y17= | Silent (SNP) | VAF 17/167 reads (10%) | catalogued as COSV56996757; called by muse, mutect2, varscan2
- GP9 | c.294C>G p.L98= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100264632, COSV56624641; called by muse, mutect2
- GPR12 | c.291C>T p.L97= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV67343956; called by muse, mutect2
- GRB10 | c.1710G>T p.L570= (on ENST00000398812; = p.L524= on NM_001001549.3) | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs960610076, COSV60006934; called by muse, mutect2, varscan2
- GTF2H4 | c.55C>T p.L19= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99461643; called by muse, mutect2, varscan2
- H2BC13 | c.138G>C p.L46= | Silent (SNP) | VAF 37/332 reads (11%) | catalogued as COSV100704325, COSV62440339; called by muse, mutect2, varscan2
- HAVCR2 | c.144C>A p.L48= | Silent (SNP) | VAF 18/145 reads (12%) | catalogued as COSV57151599, COSV57152149; called by muse, mutect2, varscan2
- HCN4 | c.1752T>C p.F584= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as COSV56080968; called by muse, mutect2, varscan2
- HDAC9 | c.1518G>A p.E506= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as rs1225058626, COSV67765559; called by muse, mutect2, varscan2
- HIP1 | c.1453C>T p.L485= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV61182906; called by muse, mutect2, varscan2
- HNRNPCL1 | c.499C>A p.R167= | Silent (SNP) | VAF 51/445 reads (11%) | catalogued as COSV58609537; called by muse, mutect2, varscan2
- HOXB6 | c.630G>T p.A210= | Silent (SNP) | VAF 29/300 reads (10%) | catalogued as COSV53311955, COSV99494750; called by muse, mutect2
- HSD17B12 | c.213A>G p.A71= | Silent (SNP) | VAF 20/268 reads (7%) | catalogued as COSV53496422; called by muse, mutect2
- HSPG2 | c.7902C>T p.I2634= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs371424140, COSV65968699; called by muse, mutect2
- IFNA4 | c.456T>A p.L152= | Silent (SNP) | VAF 50/488 reads (10%) | catalogued as COSV101427037, COSV70180352; called by muse, varscan2
- IGKV5-2 | c.54C>A p.T18= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs773272125; called by muse, mutect2, varscan2
- IGLV11-55 | c.345C>T p.C115= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as rs754845127, COSV101135361; called by muse, mutect2, varscan2
- IL7R | c.423A>G p.E141= | Silent (SNP) | VAF 52/127 reads (41%) | catalogued as COSV57405372; called by muse, mutect2, varscan2
- INTS1 | c.3141C>T p.A1047= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV67176162; called by muse, mutect2, varscan2
- IRF8 | c.504C>T p.A168= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV99236274; called by muse, mutect2, varscan2
- IRX6 | c.750G>T p.G250= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs562405725, COSV51858883; called by muse, mutect2, varscan2
- ITGAL | c.2343G>A p.L781= | Silent (SNP) | VAF 15/183 reads (8%) | catalogued as rs1567483136, COSV63319857; called by muse, mutect2
- ITGAM | c.1872C>A p.I624= (on ENST00000648685 / NM_001145808.2; = p.I623= on NM_000632.4) | Silent (SNP) | VAF 38/447 reads (9%) | catalogued as COSV54933379; called by muse, mutect2
- ITLN2 | c.960A>G p.V320= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs1243812883, COSV63537323; called by mutect2, varscan2
- KCND2 | c.552C>A p.A184= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV58567391; called by muse, mutect2
- KIAA1549 | c.5229G>T p.T1743= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV54303760, COSV54309135; called by muse, mutect2, varscan2
- KIF2C | c.1137G>T p.R379= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV64763815; called by muse, mutect2, varscan2
- KLHL25 | c.882C>A p.G294= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100563525; called by muse, mutect2, varscan2
- KLHL38 | c.1635C>T p.C545= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV58085796; called by muse, mutect2, varscan2
- KLK5 | c.666G>C p.P222= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV60449387; called by muse, mutect2, varscan2
- KRTAP6-1 | c.147T>C p.Y49= | Silent (SNP) | VAF 43/187 reads (23%) | catalogued as COSV58168426, COSV58168484; called by muse, mutect2, varscan2
- LDHB | c.972G>A p.L324= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs769013947, COSV63364242; called by muse, mutect2, varscan2
- LILRA1 | c.456C>G p.G152= | Silent (SNP) | VAF 35/169 reads (21%) | catalogued as COSV52177392; called by muse, mutect2, varscan2
- LRP1B | c.11382A>G p.Q3794= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV67181900; called by muse, mutect2, varscan2
- LRRC45 | c.271C>T p.L91= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV60710281; called by muse, mutect2
- LRRTM1 | c.489C>T p.L163= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV54437725; called by muse, mutect2, varscan2
- LSAMP | c.831G>A p.V277= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV61273299; called by muse, mutect2
- MAGEA6 | c.775C>A p.R259= | Silent (SNP) | VAF 65/237 reads (27%) | catalogued as COSV100262751; called by muse, mutect2, varscan2
- MAP2K5 | c.1233A>G p.E411= (on ENST00000178640 / NM_145160.3; = p.E401= on NM_002757.4) | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV51609262; called by muse, mutect2
- MAP3K19 | c.1971T>A p.A657= | Silent (SNP) | VAF 17/182 reads (9%) | catalogued as COSV100208332; called by muse, mutect2
- MAP3K2 | c.1377G>T p.V459= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV61292731; called by muse, mutect2, varscan2
- MEIOC | c.2184T>C p.D728= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100740191; called by muse, mutect2, varscan2
- MEIS2 | c.1290A>T p.P430= | Silent (SNP) | VAF 43/388 reads (11%) | catalogued as COSV54930600; called by muse, mutect2, varscan2
- MID1 | c.1437G>A p.L479= | Silent (SNP) | VAF 19/167 reads (11%) | catalogued as COSV58191141; called by muse, mutect2, varscan2
- MKI67 | c.6879A>G p.P2293= | Silent (SNP) | VAF 38/339 reads (11%) | catalogued as COSV64072262; called by muse, mutect2, varscan2
- MLC1 | c.582C>A p.V194= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV61115686; called by muse, mutect2, varscan2
- MMP16 | c.999C>A p.P333= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV54148710; called by muse, mutect2, varscan2
- MYBPC3 | c.1722G>A p.R574= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV57022259; called by muse, mutect2, varscan2
- MYEF2 | c.759C>T p.F253= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as rs999237407, COSV51045841; called by muse, mutect2, varscan2
- MYO18B | c.1746C>T p.V582= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as COSV59124074; called by muse, mutect2, varscan2
- NALCN | c.5094T>A p.S1698= | Silent (SNP) | VAF 19/260 reads (7%) | catalogued as COSV51914819; called by muse, mutect2
- NAP1L3 | c.1326C>T p.F442= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100220640, COSV59073368, COSV59074349; called by muse, mutect2
- NIM1K | c.393C>A p.P131= | Silent (SNP) | VAF 31/149 reads (21%) | catalogued as COSV58138992; called by muse, mutect2, varscan2
- NOX4 | c.183A>T p.A61= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV54445862; called by muse, mutect2, varscan2
- NPHP4 | c.1218C>T p.T406= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1484018828, COSV65392835; called by muse, mutect2
- NRF1 | c.717C>T p.P239= | Silent (SNP) | VAF 32/210 reads (15%) | catalogued as COSV56209662; called by muse, mutect2, varscan2
- NTRK3 | c.561C>T p.L187= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV58106897, COSV58150597; called by muse, mutect2, varscan2
- OCA2 | c.1200A>T p.I400= | Silent (SNP) | VAF 12/209 reads (6%) | catalogued as COSV62337169; called by muse, mutect2
- OR2F1 | c.99C>A p.V33= | Silent (SNP) | VAF 26/253 reads (10%) | catalogued as COSV67330709; called by muse, mutect2, varscan2
- OR2H2 | c.45C>T p.F15= | Silent (SNP) | VAF 27/228 reads (12%) | catalogued as COSV63544487; called by muse, mutect2, varscan2
- OR2L13 | c.54C>A p.P18= | Silent (SNP) | VAF 42/187 reads (22%) | catalogued as COSV63547381; called by muse, mutect2, varscan2
- OR2T33 | c.366G>T p.A122= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV58813596, COSV58814743; called by muse, mutect2, varscan2
- OR2T4 | c.547C>T p.L183= | Silent (SNP) | VAF 82/266 reads (31%) | catalogued as COSV63543190; called by muse, mutect2, varscan2
- OR4F15 | c.186C>A p.L62= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as COSV59968222; called by muse, mutect2, varscan2
- OR4N2 | c.585G>A p.V195= | Silent (SNP) | VAF 11/347 reads (3%) | catalogued as COSV60049743; called by muse, mutect2
- OR4N5 | c.699G>A p.K233= | Silent (SNP) | VAF 36/162 reads (22%) | catalogued as COSV100374217, COSV61321055; called by muse, mutect2, varscan2
- OR4S1 | c.409C>A p.R137= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV100180201, COSV100180333; called by muse, mutect2, varscan2
- OR5R1 | c.189C>T p.L63= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV56571354, COSV56572680; called by muse, mutect2
- OR6B2 | c.102C>A p.T34= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as rs1390315526, COSV53152433; called by muse, mutect2, varscan2
- OR6B3 | c.933C>A p.A311= | Silent (SNP) | VAF 45/190 reads (24%) | catalogued as rs201522340, COSV60115524; called by muse, varscan2
- OR8B12 | c.903G>A p.R301= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV100172935, COSV60910789; called by muse, mutect2, varscan2
- PCDH15 | c.3738G>A p.L1246= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV57256602, COSV57335842; called by muse, mutect2, varscan2
- PCDHB1 | c.1611G>T p.G537= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV60629299; called by muse, mutect2, varscan2
- PCLO | c.6417A>G p.E2139= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs772016293, COSV61612531, COSV61635435; called by muse, varscan2
- PCOLCE2 | c.1164C>A p.G388= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV55997175; called by muse, mutect2, varscan2
- PDE10A | c.1386C>T p.F462= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV63090179; called by muse, mutect2, varscan2
- PEX6 | c.1911C>G p.A637= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as COSV55101500; called by muse, mutect2, varscan2
- PFKL | c.903G>C p.R301= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV62462526; called by muse, mutect2
- PGK1 | c.1242C>T p.L414= | Silent (SNP) | VAF 59/486 reads (12%) | catalogued as rs781803907, COSV59370696; called by muse, mutect2, varscan2
- PKD1L1 | c.6831G>A p.E2277= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV56957074; called by muse, mutect2, varscan2
- PLCH1 | c.2013C>T p.P671= (on ENST00000340059 / NM_001130960.2; = p.P683= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV58184808; called by muse, mutect2, varscan2
- PLEKHA6 | c.1650G>T p.L550= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV99691807; called by muse, mutect2, varscan2
- PLEKHG5 | c.2436C>T p.F812= (on ENST00000400915 / NM_001042663.3; = p.F775= on NM_020631.6) | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV61067459; called by muse, mutect2, varscan2
- POLR3A | c.705T>A p.V235= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV64930067; called by muse, mutect2, varscan2
- POLR3C | c.1473C>A p.I491= | Silent (SNP) | VAF 38/237 reads (16%) | catalogued as COSV57906452; called by muse, mutect2, varscan2
- POLR3D | c.729A>T p.P243= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100120028; called by muse, mutect2, varscan2
- POLR3G | c.84T>C p.P28= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV101209775; called by muse, mutect2, varscan2
- POM121L12 | c.495C>T p.A165= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs767392618, COSV101374866, COSV68692116; called by muse, mutect2, varscan2
- PPID | c.936C>T p.R312= | Silent (SNP) | VAF 35/201 reads (17%) | catalogued as COSV56986831; called by muse, mutect2, varscan2
- PRAMEF18 | c.577C>T p.L193= | Silent (SNP) | VAF 32/938 reads (3%) | called by muse, mutect2
- PRAMEF6 | c.1353C>T p.I451= | Silent (SNP) | VAF 26/657 reads (4%) | called by muse, mutect2
- PRR23B | c.459G>A p.E153= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100272002; called by muse, mutect2, varscan2
- PSMC6 | c.471G>T p.R157= (on ENST00000612399; = p.R143= on NM_002806.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as COSV101471194; called by muse, mutect2, varscan2
- PTGFR | c.666C>A p.I222= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV66114098, COSV66116413; called by muse, mutect2
- QARS1 | c.2262C>T p.D754= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs765549972, COSV60273654; called by muse, varscan2
- RADIL | c.531G>T p.T177= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs370273724, COSV101271329; called by muse, mutect2, varscan2
- RFX4 | c.522C>T p.L174= (on ENST00000392842 / NM_213594.3; = p.L80= on NM_032491.6) | Silent (SNP) | VAF 21/162 reads (13%) | catalogued as rs530203287, COSV57571541; called by muse, mutect2, varscan2
- RGL3 | c.2020C>T p.L674= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100992889; called by muse, mutect2, varscan2
- RGR | c.816C>A p.G272= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV63893248; called by muse, mutect2, varscan2
- RPN1 | c.348G>A p.K116= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV56188990; called by muse, mutect2, varscan2
- RTF1 | c.603G>A p.E201= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV67477636; called by muse, mutect2
- RYR2 | c.8637C>A p.A2879= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV63657313; called by muse, mutect2, varscan2
- SCN1A | c.4515G>A p.K1505= (on ENST00000303395 / NM_001202435.3; = p.K1494= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV57658467; called by muse, mutect2
- SEC14L4 | c.1014C>T p.P338= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs765687119, COSV55397932; called by muse, mutect2, varscan2
- SEPTIN5 | c.192C>T p.L64= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs1237478215, COSV63530316; called by muse, mutect2, varscan2
- SLC22A10 | c.1020G>A p.L340= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV60419809; called by muse, mutect2, varscan2
51 further variants in this file (0 protein-altering or splice-affecting, 36 silent, 15 other) are not listed here.
